Gene-level copy-number profile of tumor specimen TARGET-40-PANZHX-01A from TARGET case TARGET-40-PANZHX, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 14.0 years (5,127 days).
Specimen TARGET-40-PANZHX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.77e0620a-2d22-5d61-9651-ca39a4a4d7c1.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PANZHX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 392 have no estimate.
https://portal.gdc.cancer.gov/files/1f7570dd-8b4f-4e71-83eb-085b424206b4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 548; copy number 1: 29,011; copy number 2: 29,774; copy number 3: 769; copy number 4: 118; copy number 12: 11.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:61,561,569–62,297,609, 1 gene (within-gene range 0–1): PTPRG.
- chr3:62,118,300–62,369,406, 3 genes (within-gene range 0–1): RNU2-10P, ID2B, PTPRG-AS1.
- chr4:5,051,480–6,200,555, 9 genes (within-gene range 0–2): STK32B, Y_RNA, RN7SKP275, LINC01587, EVC2, EVC, CRMP1, C4orf50, MIR378D1.
- chr4:6,064,977–6,070,162, 1 gene: AC092442.1.
- chr5:96,050,115–96,215,519, 2 genes (within-gene range 0–1): MIR583HG, MIR583.
- chr6:162,568,379–162,569,728, 1 gene: KRT8P44.
- chr12:1,380,060–1,391,502, 2 genes (within-gene range 0–1): AC004672.1, AC004672.2.
- chr19:42,752,686–42,855,691, 1 gene (within-gene range 0–2): PSG8.
- chr19:42,821,863–42,950,387, 6 genes: PSG8-AS1, PSG10P, PSG1, PSG6, PSG7, CEACAMP7.
- chr19:43,007,656–43,041,248, 2 genes: PSG11, CEACAMP8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:13,333,414–13,648,400, 10 genes, copy number 12: HSP90AB2P, RAB28, AC006445.3, LINC01097, NKX3-2, LINC01096, BOD1L1, MIR5091, AC006445.2, AC006445.1.
- chr4:13,777,377–13,782,157, 1 gene, copy number 12: AC007126.1.

Autosomal genes at a single copy (total copy number 1): 26,590. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
